Surgical pathology report (de-identified scan), TCGA case TCGA-W3-A825, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  John Wayne Cancer Center, specimen TCGA-W3-A825-06A (Metastatic).

[page 1 of 3]
Coll:
Recd:

ADDENDUM

Addendum #1 Entered:

Please see attached report (Drug Resistance Assay) from dated

Addendum Signed signature on file

CLINICAL HISTORY

Metastatic melanoma to left lung.

ICD O-3
Melanoma, malignant NOS
8720/3
Site @ Lung, lower lobe
0343
Jill 2/1/13

GROSS DESCRIPTION

1. Labeled "left sentinel node inferior pulmonary ligament, lower lobe": The specimen consists of a 1.5 x 0.7 x 0.6 cm black gray lymph node. Lymph node bisected and entirely submitted as 1FSA. HMB-45 and S-100 are ordered.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):

- Sentinel lymph node negative.

2. Labeled "left subpleural nodule upper lobe adjacent to superior pulmonary vein": The specimen consists of two irregular portions of red tan soft tissue measuring 0.5 and 0.8 cm. Entirely submitted as 2FSA.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):

- Hyaline nodule, alveolar collapse.
- Focus of atypical cells, favor histiocytes, benign.

3. Labeled "second nodule anterior segment of left lower lobe": The specimen consists of a 2.5 x 1.0 x 0.6 cm irregular portion of red tan lung tissue. A 0.6 cm yellow tan well circumscribed firm nodule is present. Specimen is bisected and entirely submitted as 3FSA.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):

- Positive for metastatic melanoma.

4. Labeled "posterior mediastinal sentinel node": The specimen consists of a 1.5

[page 2 of 3]
x 0.9 x

0.4 cm black gray lymph node. Lymph node bisected and entirely submitted as 4A.
HMB-45
and S-100 ordered.

5. Labeled "left lower lobe": The specimen consists of a 16.0 x 11.0 x 4.0 cm lower lobe of left lung. Visceral pleura is tan pink gray purple with a 6.0 x 2.5 cm rectangular defect. A 3.0 x 3.0 x 2.5 cm deeply blue stained tan gray somewhat friable mass is exposed at defect site. A moderate amount of the mass has been previously harvested. Mass focally abuts visceral pleura but does not appear to involve pleura. Mass is approximately 5.0 cm from bronchial resection margin. Surrounding lung parenchyma along diaphragmatic aspect is somewhat golden yellow tan. Remaining uninvolved lung parenchyma is red tan unremarkable. Several hilar lymph nodes are present ranging from 0.3 to 1.3 cm. Representatively sectioned as 5A - bronchial and vascular resection margins, 5B - hilar lymph nodes, 5C - two hilar lymph nodes, each bisected; 5D-5F - representative sections of mass, 5G - lung parenchyma along diaphragmatic surface adjacent to mass, 5H - distant uninvolved lung parenchyma.

6. Labeled "lymph node adjacent to pulmonary artery": The specimen consists of a 1.0 x 0.7 x 0.2 cm black lymph node. Lymph node entirely submitted as 6A.

7. Labeled "7th left rib": The specimen consists of a 1.7 x 1.5 x 0.7 cm irregular portion of red tan gray rib. No discrete lesions identified. Representatively sectioned following decalcification as 7A.

Microscopic sections are prepared and interpreted.

COMMENT

The small lymphocytic lymphoid aggregate noted in bone is non-paratrabeular and is considered within normal limits for a patient of this age. Clinical correlation recommended, including CBC with differential to exclude peripheral blood lymphocytosis.

DIAGNOSIS

1. SENTINEL LYMPH NODE, LEFT INFERIOR PULMONARY LIGAMENT, LOWER LOBE, BIOPSY:
- LYMPH NODE WITH FOCAL ANTHRACOSIS, OTHERWISE NO SIGNIFICANT ABNORMALITY.
- NEGATIVE FOR MALIGNANCY.
- S-100 AND HMB-45 STAINS BY IMMUNOPEROXIDASE NEGATIVE FOR TUMOR CELLS.
2. LEFT SUBPLEURAL NODULE, UPPER LOBE ADJACENT TO SUPERIOR PULMONARY VEIN, BIOPSY:
- SMALL PLEURAL/SUBPLEURAL SCAR.
- NEGATIVE FOR MALIGNANCY.
3. SECOND NODULE, ANTERIOR SEGMENT OF LEFT LOWER LOBE, EXCISION:

[page 3 of 3]
- METASTATIC MELANOMA, 0.8 CM PARENCHYMAL TUMOR DEPOSIT.
- APPROXIMATELY 25% TUMOR NECROSIS, NO SIGNIFICANT LYMPHOCYTIC REACTION.
4. SENTINEL LYMPH NODE, POSTERIOR MEDIASTINAL, BIOPSY:
- LYMPH NODE WITH FOCAL ANTHRACOSIS, OTHERWISE NO SIGNIFICANT ABNORMALITY.
- NEGATIVE FOR MALIGNANCY.
- S-100 AND HMB-45 STAINS BY IMMUNOPEROXIDASE NEGATIVE FOR TUMOR CELLS.
5. LUNG, LEFT LOWER LOBE, LOBECTOMY:
- METASTATIC MELANOMA, 3.0 CM SUBPLEURAL TUMOR MASS (HISTOLOGICALLY ALMOST ENTIRELY VIABLE TUMOR WITH MINIMAL LYMPHOCYTIC REACTION).
- ADJACENT LUNG SHOWING NONSPECIFIC CHANGES.
- REMOTE LUNG TISSUE WITH MILD EMPHYSEMATOUS CHANGES.
- PROXIMAL BRONCHIAL AND VASCULAR MARGINS OF LOBECTOMY NEGATIVE FOR MALIGNANCY.
- FIVE PERIHILAR/BRONCHOPULMONARY LYMPH NODES NEGATIVE FOR MALIGNANCY (WITH FOCAL REACTIVE FOLLICULAR HYPERPLASIA).
6. LYMPH NODE, ADJACENT TO PULMONARY ARTERY, BIOPSY:
- LYMPH NODE WITH ANTHRACOSIS, OTHERWISE NO SIGNIFICANT ABNORMALITY.
- NEGATIVE FOR MALIGNANCY.
7. SEVENTH LEFT RIB, REMOVAL:
- RIB SEGMENT CONTAINING NORMOCELLULAR BONE MARROW.
- SMALL NON-PARATRABECULAR LYMPHOID AGGREGATE NOTED (SEE COMMENT).
- NEGATIVE FOR DIAGNOSTIC MALIGNANCY.

signed Electronically signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file dd209a5c-3619-4852-a1b2-cafaa4800f9f (TCGA-W3-A825.B8EDB8FD-8FB4-4245-A218-E8CF051497E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).